HCMI case HCM-BROD-0036-C41 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Miscellaneous Bone Tumors; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/307c905f-c276-4501-988a-b083f9462a98

Demographics
Sex at birth: male; Race: white; Year of birth: 2002; Vital status: Dead; Days to death: 4,687 days (12.8 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Ewing sarcoma: ICD-O-3 morphology code: 9260/3; ICD-10 code: C78.2; Tissue or organ of origin: Bone, NOS; Site of resection or biopsy: Pleura, NOS; Classification of tumor: metastasis; Age at diagnosis: 13.7 years (4,997 days); Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cyclophosphamide + Dactinomycin + Vincristine; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: VAC; Days to treatment start: 1,157 days (3.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Etoposide + Ifosfamide; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Days to treatment start: 1,157 days (3.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Irinotecan + Temozolomide + Vincristine; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: VIT; Days to treatment start: 1,157 days (3.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Regorafenib; Treatment intent type: Neoadjuvant; Days to treatment start: 4,506 days (12.3 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 4,656 days (12.7 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Neoadjuvant.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Neoadjuvant.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 4,656 days (12.7 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 4,656 days (12.7 years).
- Days to follow up: 4,687 days (12.8 years); Disease response: Stable Disease; Progression or recurrence: No.

Molecular and laboratory tests
- CD99 (IHC): Positive.
- EWSR1–FLI1 translocation: Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 21.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (4 samples)
- Sample HCM-BROD-0036-C41-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample HCM-BROD-0036-C41-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0036-C41-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 12.
- Sample HCM-BROD-0036-C41-86M: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen.
